Somatic mutation profile of tumor specimen C3L-01885-03 (aliquot CPT0092790009) from CPTAC case C3L-01885, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.8 years (24,752 days).
Specimen C3L-01885-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b76a299-dc9b-4ae7-b376-cdad6b4f4cb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01885-31 (Blood Derived Normal), aliquot CPT0093830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bec41ac-e723-4a28-a7cf-c791e2e4d4e8

The open-access MAF lists 99 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 19, Frame Shift Del 6, Intron 3, Splice Region 2, RNA 2, 5'UTR 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.5377C>T p.P1793S | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.327); catalogued as rs377189756; called by muse, mutect2
- BMP3 | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51086313; called by muse, mutect2, varscan2
- CARS2 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178890093; called by muse, mutect2, varscan2
- CDH8 | c.2243G>C p.G748A | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100180102; called by muse, mutect2, varscan2
- CTSS | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100935027; called by muse, varscan2
- DIS3 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs1410948691, COSV66708227, COSV99060477; called by muse, mutect2, varscan2
- FAT2 | c.4763C>A p.A1588D | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55815928; called by muse, mutect2, varscan2
- FCSK | c.2788G>A p.V930M | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs763297173, COSV55372490; called by muse, mutect2, varscan2
- KCNH2 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as CM087230, CM097313; called by muse, mutect2, varscan2
- MACF1 | c.13672T>C p.W4558R (on ENST00000372915; = p.W2491R on NM_012090.5) | Missense Mutation (SNP) | VAF 59/230 reads (26%) | catalogued as rs1557621299; called by muse, mutect2, varscan2
- MAP9 | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1379505531; called by muse, mutect2, varscan2
- PBRM1 | c.3649del p.L1217* (on ENST00000296302 / NM_001366071.2; = p.L1192* on NM_018313.5) | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | catalogued as COSV56262527; called by mutect2, pindel, varscan2
- PKHD1 | c.11841G>A p.M3947I | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100945119; called by muse, mutect2, varscan2
- PLEKHS1 | c.38del p.N13Mfs*21 (on ENST00000369310 / NM_182601.1; = p.N19Mfs*21 on NM_024889.5) | Frame Shift Del (DEL) | VAF 62/259 reads (24%) | catalogued as rs1285529804; called by mutect2, pindel, varscan2
- SGPL1 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs141665233; called by muse, mutect2, varscan2
- SOX11 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.065); catalogued as COSV100431568; called by muse, mutect2
- VHL | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 62/255 reads (24%) | catalogued as COSV56553344; called by muse, mutect2, varscan2
- ZNF514 | c.923G>T p.R308M | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754599113; called by muse, mutect2, varscan2
- ABCA1 | c.4099A>G p.I1367V | Missense Mutation (SNP) | VAF 82/357 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ACTL9 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AQR | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/156 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- BIVM-ERCC5 | c.3101C>G p.P1034R | Missense Mutation (SNP) | VAF 27/307 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.048); called by muse, mutect2
- BMS1 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- CCDC178 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- CCDC73 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CDH16 | c.1975del p.A659Pfs*7 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- CHMP4B | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 87/491 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- DROSHA | c.2572C>G p.Q858E | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- EXTL1 | c.1065del p.S356Pfs*67 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | called by mutect2, pindel, varscan2
- FANCI | c.3757C>T p.L1253F (on ENST00000310775 / NM_001376911.1; = p.L1193F on NM_018193.3) | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GBF1 | c.2708T>C p.V903A (on ENST00000369983 / NM_001377137.1; = p.V902A on NM_004193.3) | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HMCN2 | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- HSD3B1 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IFIT5 | c.492del p.K165Rfs*32 | Frame Shift Del (DEL) | VAF 47/233 reads (20%) | called by mutect2, pindel, varscan2
- IL20RB | c.226A>C p.S76R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INO80D | c.818C>G p.P273R | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- IRF2BP2 | c.1486T>C p.S496P | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGB1BP1 | c.383A>C p.D128A | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.393); called by mutect2, varscan2
- KIAA1109 | c.12985T>G p.F4329V | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KRTAP5-8 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 88/448 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- LMNA | c.1158-8C>T | Splice Region (SNP) | VAF 20/344 reads (6%) | called by muse, mutect2
- MAMDC4 | c.2282A>G p.N761S (on ENST00000445819; = p.N682S on NM_206920.3) | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTMR4 | c.1390A>C p.N464H | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NUDT4 | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUP188 | c.1562T>G p.V521G | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OGA | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.04); called by muse, mutect2
- PIWIL3 | c.2558G>C p.C853S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEE | c.2227A>C p.M743L | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- RBM15 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- RGP1 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RHBDL3 | c.656T>G p.F219C | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIIAD1 | c.85-2A>T p.X29_splice | Splice Site (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- RUNDC1 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- SCN9A | c.897T>A p.F299L | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCAD1 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SPEF2 | c.4921dup p.T1641Nfs*35 | Frame Shift Ins (INS) | VAF 47/341 reads (14%) | called by mutect2, pindel, varscan2
- SRCAP | c.1966C>G p.L656V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYMPK | c.1714G>C p.A572P | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- TAF1B | c.1282A>C p.K428Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TBC1D30 | c.1847C>G p.S616C (on ENST00000542120; = p.S453C on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- TECR | c.164-7T>C | Splice Region (SNP) | VAF 88/434 reads (20%) | called by muse, mutect2, varscan2
- TNFAIP8L3 | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 41/413 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); called by muse, mutect2
- TPP1 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 105/455 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TSKS | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTC19 | c.766_767del p.A256Tfs*5 | Frame Shift Del (DEL) | VAF 71/374 reads (19%) | called by mutect2, pindel, varscan2
- TTC6 | c.832C>G p.P278A (on ENST00000267368; = p.P1644A on NM_001310135.3) | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TUBGCP6 | c.5210T>C p.I1737T | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBASH3B | c.1324A>T p.T442S | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.081); called by muse, mutect2
- ZNF236 | c.794_796del p.K265_G266delinsR | In Frame Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- ZNF518B | c.609T>A p.D203E | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZNF735 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- COLQ | c.1104T>C p.T368= | Silent (SNP) | VAF 92/366 reads (25%) | called by muse, mutect2, varscan2
- DHX37 | c.1836G>C p.G612= | Silent (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- EPHB2 | c.1962G>A p.T654= (on ENST00000400191 / NM_001309193.2; = p.T655= on NM_004442.7) | Silent (SNP) | VAF 67/299 reads (22%) | catalogued as rs749583000; called by muse, mutect2, varscan2
- F3 | c.729C>T p.G243= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as rs769591046, COSV61845033; called by muse, mutect2, varscan2
- HNRNPK | c.132A>G p.E44= | Silent (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- IDH3B | c.210G>A p.V70= | Silent (SNP) | VAF 96/517 reads (19%) | called by muse, mutect2, varscan2
- KIAA0100 | c.4926C>A p.P1642= | Silent (SNP) | VAF 52/244 reads (21%) | catalogued as COSV66493756; called by muse, mutect2, varscan2
- KRT23 | c.468C>T p.D156= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as rs766813414; called by muse, mutect2
- MAGEB5 | c.234T>C p.F78= | Silent (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- MGAT4C | c.588C>A p.V196= | Silent (SNP) | VAF 13/275 reads (5%) | called by muse, mutect2
- PLCG2 | c.1104G>A p.P368= | Silent (SNP) | VAF 17/215 reads (8%) | catalogued as rs769107090, COSV63872356; called by muse, mutect2
- PNMA2 | c.387G>T p.V129= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- SBNO1 | c.3144T>C p.I1048= (on ENST00000420886; = p.I1047= on NM_018183.5) | Silent (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
- SLC17A3 | c.1152T>C p.N384= | Silent (SNP) | VAF 73/340 reads (21%) | called by muse, mutect2, varscan2
- SPRY2 | c.774C>A p.V258= | Silent (SNP) | VAF 139/602 reads (23%) | called by muse, mutect2, varscan2
- TLR8 | c.2460A>G p.T820= (on ENST00000218032 / NM_138636.5; = p.T838= on NM_016610.4) | Silent (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- TRIM23 | c.180C>A p.L60= | Silent (SNP) | VAF 94/282 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.4572T>C p.D1524= (on ENST00000591111; = p.D1478= on NM_003319.4) | Silent (SNP) | VAF 82/332 reads (25%) | called by muse, mutect2, varscan2
- ZC3H6 | c.1620A>G p.T540= | Silent (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- AL590867.2 | n.329A>C | RNA (SNP) | VAF 93/430 reads (22%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499837 A>G | 5'Flank (SNP) | VAF 29/137 reads (21%) | called by muse, mutect2, varscan2
- C8orf31 | n.494A>C | RNA (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- CLU | c.*665C>T | 3'UTR (SNP) | VAF 87/425 reads (20%) | catalogued as rs1357591361; called by muse, mutect2, varscan2
- GRHPR | c.734+367T>C | Intron (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- HPN | c.414-20T>A | Intron (SNP) | VAF 82/300 reads (27%) | called by muse, mutect2, varscan2
- JAM2 | c.-4G>A | 5'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2
- LYPLA2 | c.471+24dup | Intron (INS) | VAF 33/154 reads (21%) | catalogued as rs753673005; called by mutect2, varscan2
- PRSS58 | c.-13T>G | 5'UTR (SNP) | VAF 44/179 reads (25%) | called by muse, mutect2, varscan2
